Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XV, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XV-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

copy No.

Date: _____

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Total organ resection – right breast

Unit in charge:

Internal referral

Physician in charge:

Material collected on:

Material received on:

ICD-0-3

Carcinoma, infiltrating mucinosa 8480/3

Site: breast, nos C50.9

for 4/12/11

Expected time of examination: up to 8 working days

Clinical diagnosis: Based on PCI, cellulae carcinomatosae – lesion covering the lower part of the breast.

Examination performed on: _____

Macroscopic description:

Right breast sized 27 x 23 x 3 cm removed without axillary tissues and with a skin flap of 27 x 14 cm. Skin injected with blue dye. Tumour sized 2 x 1.8 x 2.5 cm found on the boundary of lower quadrants, located 3.0 cm from the lower edge, 1.0 cm from the base and 2.5 cm from the skin.

The other tumour sized 3.2 x 1.9 x 4.5 cm found 2 cm away from the first one (margins: lower boundary 1.0 cm, base 1.0 cm, skin 3 cm).

Microscopic description:

Carcinoma mucinosum invasivum bifocale - NHG2 (3+2+1/5 mitoses/10 HPF - visual area 0.55mm).

Foci of carcinoma ductale in situ (DCIS) found within the tumour (papillary, solid, mucous type, with medium nuclear atypia, without necrosis, 20% of the tumour). Carcinoma intraductale mamillae.

Glandular tissue showing parenchymal atrophy.

Histopathological diagnosis:

Including test No.:

Carcinoma mucinosum invasivum et ductale in situ mammae dextrae. Invasive mucinous carcinoma and ductal carcinoma in situ of the right breast. (NHG2, pT2, pNO (sn))

Compliance valid

Examination performed on: _____

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained using rabbit antibody Ventana PATHWAY HER-2/neu (4B5).

Score = 2+ FISH verification recommended

Compliance validated by:

[page 2 of 2]
Examination: Histopathological examination

page 2 / 2

Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on:

Result of immunohistochemical examination:

RESULT OF HER2/neu GENE AMPLIFICATION with the FISH method by Path Vysion HER2 DNA Probe Kit FINAL RESULT:

HER-2 GENE AMPLIFICATION NOT FOUND

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file ac9f8e3b-8ccf-46b1-81fe-f59608bb40f9 (TCGA-D8-A1XV.D3AC6B8A-CC8F-475C-BD2E-A869BD07D94C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).